TCGA case TCGA-YH-A8SY — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas; Tissue source site: Stanford University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/503d7e36-df78-428d-9971-09ff707645c2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 73.5 years (26,859 days); Year of diagnosis: 2011; Method of diagnosis: Cytology; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 388 days (1.1 years); Sites of involvement: Pancreas Head; Tumor grade category: Three Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 16; Lymph nodes tested: 27; Tumor largest dimension diameter: 4.1 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Whipple.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 388.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol days per week: 2.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YH-A8SY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 720 mg.
  Slide TCGA-YH-A8SY-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YH-A8SY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tobacco smoking history indicator: 1; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 2; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 388 days; disease-specific survival: no event (censored), 388 days; progression-free interval: no event (censored), 388 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YH-A8SY-01A-11D-A376-01): tumor purity 0.36, ploidy 1.77, whole-genome doublings 0.
